Somatic mutation profile of tumor specimen 0DZOFO from CCDI case PBCUHP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DZOFO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eea733b5-d962-4bb7-9ad7-5345d288f206.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZOFC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a711b0ee-1fe6-4bab-93a4-0c663b966635

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SEMA5B | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 171/393 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs747854019; called by muse, mutect2, varscan2
- BHMT | c.805T>C p.F269L | Missense Mutation (SNP) | VAF 168/419 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.47); called by muse, mutect2
- RYR1 | c.2712G>A p.P904= | Silent (SNP) | VAF 206/451 reads (46%) | catalogued as rs139339574; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- OBSCN | c.11659+5173C>T | Intron (SNP) | VAF 111/210 reads (53%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.739+60G>A | Intron (SNP) | VAF 14/264 reads (5%) | called by muse, mutect2
